Somatic mutation profile of tumor specimen TCGA-91-6836-01A (aliquot TCGA-91-6836-01A-21D-1855-08) from TCGA case TCGA-91-6836, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.6 years (19,216 days).
Specimen TCGA-91-6836-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe36c53b-029a-473c-9277-aa9663cb020e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-6836-11A (Solid Tissue Normal), aliquot TCGA-91-6836-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6867f860-8669-4788-a3e3-f4e22380986f

The open-access MAF lists 483 somatic variants for this specimen: 372 protein-altering or splice-affecting, 99 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 314, Silent 99, Nonsense Mutation 28, Splice Site 11, RNA 7, Frame Shift Del 7, Frame Shift Ins 5, Splice Region 4, Intron 4, Translation Start Site 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.3556+1G>T p.X1186_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | catalogued as rs184388696, CS004618, CS951354, COSV54435060; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 53/66 reads (80%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB11 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55585069, COSV55589069; called by muse, mutect2, varscan2
- ABCC9 | c.4647G>T p.K1549N | Missense Mutation (SNP) | VAF 220/276 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV53962341; called by muse, mutect2, varscan2
- ABCD2 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100429850, COSV58049378; called by muse, mutect2, varscan2
- ACAN | c.4904G>A p.G1635E | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV61355594; called by muse, mutect2, varscan2
- ADAMTS16 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs776235298, COSV56977650; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1460G>T p.W487L | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99716342; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1461G>T p.W487C | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99717584, COSV99721200; called by muse, mutect2, varscan2
- ADCY5 | c.925G>C p.V309L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV71901273; called by muse, varscan2
- ADGRL2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1355443553, COSV54651553; called by muse, mutect2, varscan2
- AGO4 | c.2422G>T p.A808S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV64616387; called by muse, mutect2
- AHNAK2 | c.8195C>T p.P2732L | Missense Mutation (SNP) | VAF 87/265 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV60907407; called by muse, mutect2, varscan2
- AHR | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54121549; called by muse, mutect2, varscan2
- AKAP9 | c.10826C>T p.T3609I (on ENST00000359028; = p.T3585I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/275 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.383); catalogued as COSV62338446; called by muse, mutect2, varscan2
- ALG10B | c.313G>T p.V105F | Missense Mutation (SNP) | VAF 99/240 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as rs772717701, COSV58142210; called by muse, mutect2, varscan2
- ALK | c.3952C>A p.L1318M | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66556933; called by muse, mutect2, varscan2
- AP3S1 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57473328; called by muse, mutect2, varscan2
- APOBEC3H | c.543+1G>A p.X181_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | catalogued as rs368222781; called by muse, mutect2, varscan2
- ARHGAP36 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.137); catalogued as rs1385758857, COSV52263703; called by muse, mutect2, varscan2
- ARHGEF1 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 69/99 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV61526229; called by muse, mutect2, varscan2
- ARL9 | c.439G>T p.E147* (on ENST00000640821 / NM_001363794.2; = p.E5* on NM_206919.2) | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV63991010; called by muse, mutect2, varscan2
- ARMC3 | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 79/155 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1205860487, COSV53056938; called by muse, mutect2, varscan2
- ATG2B | c.5919G>T p.K1973N | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV55889384; called by muse, mutect2, varscan2
- ATP1A4 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV63625405; called by muse, mutect2
- AVL9 | c.1109T>A p.I370N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59463860; called by muse, varscan2
- BACH2 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57584070; called by muse, mutect2, varscan2
- BAIAP3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs534433844, COSV60977163; called by muse, mutect2, varscan2
- BBS12 | c.1880C>T p.T627I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1203588853, COSV100044856; called by muse, mutect2, varscan2
- BOC | c.2963G>A p.R988K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV56346895; called by muse, varscan2
- BOD1L1 | c.9136G>T p.V3046L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV50006480; called by muse, mutect2, varscan2
- BRINP3 | c.2047C>A p.L683M | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100819615, COSV66513180; called by muse, mutect2, varscan2
- C1QC | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1370020109, COSV65889236; called by muse, mutect2, varscan2
- C8orf76 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 57/95 reads (60%) | catalogued as COSV52689811; called by muse, mutect2, varscan2
- CACNG3 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50064027; called by muse, varscan2
- CARD14 | c.1851+7C>T | Splice Region (SNP) | VAF 8/53 reads (15%) | catalogued as rs762847886, COSV100712505; called by muse, mutect2, varscan2
- CBX5 | c.327G>T p.Q109H | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV99267449; called by muse, mutect2, varscan2
- CCDC178 | c.2575A>T p.T859S (on ENST00000383096 / NM_001105528.3; = p.T821S on NM_198995.3) | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV55758809; called by muse, mutect2, varscan2
- CCNB3 | c.541T>A p.C181S | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV52069799; called by muse, mutect2, varscan2
- CD109 | c.227C>G p.A76G | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV54645119; called by muse, mutect2, varscan2
- CD163L1 | c.3976C>A p.H1326N | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as COSV58010763; called by muse, mutect2, varscan2
- CDH9 | c.2279G>T p.C760F | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs772806219, COSV50251711, COSV50279379; called by muse, mutect2, varscan2
- CDK11B | c.1543G>C p.V515L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs753220778, COSV100477929, COSV58336614; called by muse, mutect2, varscan2
- CDKL3 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99527694; called by mutect2, varscan2
- CEMIP2 | c.3117G>T p.M1039I | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV65484270; called by muse, mutect2, varscan2
- CLDN4 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV52894859; called by muse, mutect2, varscan2
- CNTN2 | c.2341T>A p.Y781N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.937); catalogued as COSV59348035; called by muse, mutect2, varscan2
- CNTNAP2 | c.1398G>T p.K466N | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as rs955617236, COSV62144213; called by muse, mutect2, varscan2
- COL1A2 | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV99798945; called by muse, mutect2, varscan2
- COL9A1 | c.1129C>A p.R377S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.897); catalogued as COSV57878516; called by muse, mutect2, varscan2
- CORIN | c.720C>A p.C240* | Nonsense Mutation (SNP) | VAF 96/248 reads (39%) | catalogued as COSV56685886; called by muse, mutect2, varscan2
- CR1L | c.1560C>A p.S520R | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.163); catalogued as rs1255042384, COSV54322483; called by muse, mutect2, varscan2
- CTNNA2 | c.1843C>A p.L615M | Missense Mutation (SNP) | VAF 103/164 reads (63%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.807); catalogued as COSV58133816; called by muse, mutect2, varscan2
- CYP11B1 | c.779G>T p.W260L | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52824774, COSV52827774; called by muse, mutect2, varscan2
- CYP2B6 | c.1331C>A p.A444E | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs368451099, COSV57842403; called by muse, mutect2, varscan2
- DCAF4L2 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as rs1295538022, COSV60476356, COSV60480625; called by muse, mutect2, varscan2
- DCDC1 | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs1238381006, COSV60833761; called by muse, mutect2, varscan2
- DCTD | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 122/251 reads (49%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.021); catalogued as COSV63866681; called by muse, varscan2
- DIRAS3 | c.330C>A p.H110Q | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.995); catalogued as COSV63970435; called by muse, mutect2, varscan2
- DISP3 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53820060; called by muse, mutect2, varscan2
- DLGAP2 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV70093836; called by muse, mutect2, varscan2
- DMD | c.3556G>T p.E1186* | Nonsense Mutation (SNP) | VAF 43/98 reads (44%) | catalogued as rs868836192, CM066781, COSV63732541, COSV63734227; called by muse, mutect2, varscan2
- DMPK | c.369G>T p.L123F | Missense Mutation (SNP) | VAF 68/103 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99352864; called by muse, mutect2, varscan2
- DNAH2 | c.5336C>A p.T1779N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66716167; called by muse, mutect2, varscan2
- DNER | c.1876C>A p.H626N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV59159938; called by muse, mutect2, varscan2
- DOT1L | c.4412G>C p.G1471A | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.79); catalogued as COSV67107899; called by muse, mutect2, varscan2
- DPP10 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV59663767; called by muse, mutect2, varscan2
- DUOX2 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50993025; called by muse, mutect2, varscan2
- DUSP22 | c.189G>T p.L63= | Splice Region (SNP) | VAF 8/83 reads (10%) | catalogued as COSV60523564; called by muse, mutect2, varscan2
- EDIL3 | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV56879390; called by muse, mutect2, varscan2
- EIF4E3 | c.662G>T p.R221L (on ENST00000425534 / NM_001134651.2; = p.R115L on NM_173359.5) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs760948130, COSV55204314, COSV99816328; called by muse, mutect2, varscan2
- EN1 | c.1080A>T p.K360N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99727042; called by muse, mutect2, varscan2
- EP400 | c.3537C>G p.C1179W | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV57762426; called by muse, varscan2
- EPB41L3 | c.1345G>T p.G449C | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59443957; called by muse, mutect2, varscan2
- EPHB6 | c.858C>G p.H286Q | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV67417241; called by muse, mutect2, varscan2
- ERCC6 | c.758C>G p.P253R | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV63387810; called by muse, mutect2, varscan2
- EYS | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV60976080; called by muse, mutect2, varscan2
- F13B | c.801C>G p.C267W | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803260, COSV66372154; called by muse, mutect2, varscan2
- FAIM2 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.287); catalogued as COSV57737799, COSV57739575; called by muse, mutect2, varscan2
- FAM227B | c.60A>T p.Q20H | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV54805251; called by muse, mutect2, varscan2
- FAM71B | c.717T>G p.H239Q | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57227469; called by muse, mutect2, varscan2
- FAT4 | c.13186G>A p.V4396M | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV58671176; called by muse, mutect2, varscan2
- FCHO1 | c.1978C>A p.P660T | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV53180643; called by muse, mutect2, varscan2
- FCRL6 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV58939897; called by muse, mutect2, varscan2
- FGF13 | c.607A>T p.M203L | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV59542816; called by muse, mutect2, varscan2
- FGGY | c.1222-2A>T p.X408_splice | Splice Site (SNP) | VAF 33/110 reads (30%) | catalogued as COSV58025957; called by muse, mutect2, varscan2
- FLG | c.11632A>T p.R3878W | Missense Mutation (SNP) | VAF 68/516 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV64236230; called by muse, mutect2, varscan2
- FLRT3 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53943868; called by muse, mutect2, varscan2
- FNDC3B | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.119); catalogued as COSV61037181; called by muse, mutect2, varscan2
- FSCN3 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50000187; called by muse, mutect2, varscan2
- G6PC2 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 70/116 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56371495; called by muse, mutect2, varscan2
- GAB4 | c.1397G>T p.S466I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV68752921; called by muse, mutect2, varscan2
- GALNT17 | c.977T>C p.I326T | Missense Mutation (SNP) | VAF 94/185 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV61147273; called by muse, mutect2, varscan2
- GCC2 | c.350A>T p.H117L | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV59173875; called by muse, mutect2, varscan2
- GDF7 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99694007; called by muse, varscan2
- GDPD4 | c.321C>A p.Y107* | Nonsense Mutation (SNP) | VAF 32/93 reads (34%) | catalogued as COSV60017036; called by muse, mutect2, varscan2
- GFM2 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV57189593; called by muse, mutect2, varscan2
- GJA1 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 56/116 reads (48%) | catalogued as CM113504, CM1510786, COSV56996910; called by muse, mutect2, varscan2
- GLI1 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV57357738; called by muse, mutect2, varscan2
- GLI3 | c.2597G>T p.G866V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV101229767; called by mutect2, varscan2
- GPATCH2 | c.830G>T p.R277I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65127250; called by muse, mutect2, varscan2
- GPCPD1 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as COSV66830113; called by muse, mutect2, varscan2
- GPR151 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV57033799, COSV57034670; called by muse, mutect2, varscan2
- GRK3 | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV60793216; called by muse, mutect2, varscan2
- GRK4 | c.1631C>T p.T544I | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61667943; called by muse, mutect2, varscan2
- H2BW1 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.968); catalogued as COSV54219694; called by muse, mutect2, varscan2
- HDAC9 | c.1578C>A p.S526R | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV67766511; called by muse, mutect2, varscan2
- HDC | c.937T>A p.C313S | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs947052592, COSV51068271; called by muse, varscan2
- HECTD4 | c.8455C>T p.R2819* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as COSV66386558; called by muse, mutect2, varscan2
- HERC2 | c.9002C>A p.S3001Y | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55306936; called by muse, mutect2, varscan2
- HIP1R | c.3051C>G p.S1017R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV53438983; called by muse, mutect2, varscan2
- HIVEP2 | c.4684A>T p.S1562C | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV50005488; called by muse, mutect2, varscan2
- HRG | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.144); catalogued as rs191554701, COSV51643956; called by muse, mutect2, varscan2
- HTR1A | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs761266205, COSV60499776, COSV99072613; called by muse, mutect2, varscan2
- IL13 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs1561668794, COSV58733930; called by muse, mutect2, varscan2
- IL37 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 108/150 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54489858; called by muse, mutect2, varscan2
- INS-IGF2 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.274); catalogued as COSV51746524; called by muse, mutect2, varscan2
- ITGA1 | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV50876426; called by muse, mutect2, varscan2
- ITGAD | c.2422G>T p.G808C | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101210381; called by muse, mutect2, varscan2
- ITGAD | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101210383; called by muse, mutect2, varscan2
- ITGAL | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63319991; called by muse, mutect2, varscan2
- JADE1 | c.1574A>G p.Q525R | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV56904206; called by muse, mutect2, varscan2
- KALRN | c.3232A>T p.K1078* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV53752681; called by muse, mutect2, varscan2
- KANK1 | c.3203A>T p.Q1068L | Missense Mutation (SNP) | VAF 99/130 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as COSV100619521; called by muse, mutect2, varscan2
- KAT6B | c.3375G>T p.R1125S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV54741805; called by muse, mutect2, varscan2
- KCNIP1 | c.628T>C p.C210R (on ENST00000411494 / NM_001034837.3; = p.C199R on NM_014592.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61080284; called by muse, mutect2, varscan2
- KCNJ12 | c.180G>T p.M60I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.139); catalogued as COSV59163231, COSV59165163; called by muse, mutect2, varscan2
- KCNK18 | c.443T>A p.L148H | Missense Mutation (SNP) | VAF 179/347 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57970861; called by muse, mutect2, varscan2
- KCNT2 | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV99652297; called by muse, mutect2, varscan2
- KCTD2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV56902341; called by mutect2, varscan2
- KCTD3 | c.2050G>C p.V684L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV52064052; called by muse, mutect2, varscan2
- KIAA0319L | c.500G>T p.R167I | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV57841749; called by muse, mutect2, varscan2
- KIAA1109 | c.4289G>T p.R1430M | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV52662009, COSV52664588; called by muse, mutect2, varscan2
- KIAA1755 | c.2207C>A p.S736Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs559589379, COSV54073545, COSV54076349; called by muse, mutect2, varscan2
- KIF4B | c.1652A>T p.Q551L | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV70527766; called by muse, mutect2, varscan2
- KIF5C | c.2365G>T p.E789* | Nonsense Mutation (SNP) | VAF 80/160 reads (50%) | catalogued as COSV68479766; called by muse, mutect2, varscan2
- KIF9 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV55517505, COSV55523499; called by muse, varscan2
- KLHL5 | c.442G>C p.G148R | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.045); catalogued as COSV54671411, COSV54675780; called by muse, mutect2, varscan2
- KMT2D | c.8742C>A p.H2914Q | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV56409718; called by muse, mutect2, varscan2
- KRTAP9-2 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV66646389; called by muse, mutect2, varscan2
- L1CAM | c.1894C>A p.R632S | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as COSV62826709, COSV62827874; called by muse, mutect2, varscan2
- LAMA2 | c.2479A>T p.S827C | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV70338054; called by muse, mutect2, varscan2
- LAMA4 | c.2251G>A p.A751T (on ENST00000230538 / NM_001105206.3; = p.A744T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs782176510, COSV57891835; called by muse, mutect2, varscan2
- LAMB2 | c.4772G>T p.R1591L | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV59730670; called by muse, mutect2, varscan2
- LAMC3 | c.4565C>A p.P1522Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV55988975; called by muse, varscan2
- LCE1E | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV64219498; called by muse, mutect2, varscan2
- LDHB | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 406/521 reads (78%) | catalogued as COSV63364295; called by muse, mutect2, varscan2
- LEPR | c.2059T>G p.C687G | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV60746709; called by muse, mutect2, varscan2
- LMNB2 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV57586396; called by muse, mutect2, varscan2
- LMNTD1 | c.24C>A p.N8K | Missense Mutation (SNP) | VAF 136/182 reads (75%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.425); catalogued as COSV51444622; called by muse, mutect2, varscan2
- LRIT2 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs777392680, COSV60559405, COSV60559705; called by muse, mutect2, varscan2
- LRRC18 | c.764+1G>A p.X255_splice | Splice Site (SNP) | VAF 55/193 reads (28%) | catalogued as COSV99628826; called by muse, mutect2, varscan2
- LRRC4B | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV65350328; called by muse, mutect2, varscan2
- LRRC4C | c.1499C>A p.S500* | Nonsense Mutation (SNP) | VAF 19/30 reads (63%) | catalogued as COSV53417826; called by muse, mutect2, varscan2
- LRRC7 | c.4123C>G p.Q1375E (on ENST00000651989 / NM_001370785.2; = p.Q1295E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as COSV50410103; called by muse, mutect2, varscan2
- LRRIQ1 | c.4013C>T p.A1338V | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438206591, COSV67825748; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.939G>C p.L313F | Missense Mutation (SNP) | VAF 135/196 reads (69%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.018); catalogued as COSV65419973; called by muse, varscan2
- LYAR | c.230G>A p.W77* | Nonsense Mutation (SNP) | VAF 24/299 reads (8%) | catalogued as COSV58642118, COSV58643848; called by muse, mutect2
- LYZL2 | c.345C>A p.S115R (on ENST00000375318; = p.S69R on NM_183058.3) | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64683644; called by muse, mutect2, varscan2
- MAGI1 | c.3925G>T p.A1309S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58314125; called by muse, mutect2, varscan2
- MAPK9 | c.907G>C p.V303L | Missense Mutation (SNP) | VAF 109/245 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV58118496; called by muse, mutect2, varscan2
- MARCHF1 | c.341G>A p.W114* (on ENST00000274056; = p.W97* on NM_017923.4) | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | catalogued as COSV56807762; called by muse, mutect2, varscan2
- MCAT | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs765693023, COSV51791790; called by muse, mutect2, varscan2
- MED17 | c.963A>T p.Q321H | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as COSV52599257; called by muse, mutect2, varscan2
- MEN1 | c.826G>T p.G276* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as CM074351, COSV53640223; called by muse, mutect2, varscan2
- MIA3 | c.2314G>T p.D772Y | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.687); catalogued as COSV60509771; called by muse, mutect2, varscan2
- MLLT3 | c.1180C>G p.P394A | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV63494686; called by muse, mutect2, varscan2
- MMRN1 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.107); catalogued as COSV53333613; called by muse, mutect2, varscan2
- MRPL42 | c.107A>T p.Y36F | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.203); catalogued as COSV100696595; called by muse, mutect2, varscan2
- MTMR12 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV53782392; called by muse, mutect2, varscan2
- MUS81 | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as COSV57258867; called by muse, mutect2, varscan2
- MXRA5 | c.169G>C p.V57L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104373076, COSV54223450, COSV54233420; called by muse, mutect2, varscan2
- MYH11 | c.5329C>A p.R1777S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV55542564, COSV55564570; called by muse, mutect2, varscan2
- MYO16 | c.920C>A p.A307D | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1410450200, COSV51777106; called by muse, mutect2, varscan2
- MYO18A | c.4868A>G p.Q1623R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs1439345995, COSV62862312; called by muse, mutect2, varscan2
- MYORG | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52626179; called by muse, mutect2, varscan2
- MYT1L | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101219417; called by muse, mutect2, varscan2
- MYT1L | c.40T>A p.S14T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101219421; called by muse, mutect2, varscan2
- NAE1 | c.1504G>T p.A502S | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV51974918; called by muse, mutect2, varscan2
- NAV3 | c.1178C>G p.A393G | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs748769258, COSV57061246, COSV57080590; called by muse, mutect2, varscan2
- NCOA6 | c.1723G>T p.G575W | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV62861252, COSV62865615; called by muse, mutect2, varscan2
- NDN | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.642); catalogued as rs769217515, COSV59360087; called by muse, mutect2, varscan2
- NDST4 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV52108641, COSV52110232; called by muse, mutect2, varscan2
- NDUFS1 | c.1417A>C p.M473L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV51907865; called by muse, mutect2, varscan2
- NEB | c.8310T>G p.Y2770* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as COSV50808433; called by muse, mutect2, varscan2
- NLN | c.42-1G>A p.X14_splice | Splice Site (SNP) | VAF 33/72 reads (46%) | catalogued as COSV66764940; called by muse, mutect2, varscan2
- NLRP5 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs939295010, COSV66761960, COSV66762753; called by muse, mutect2, varscan2
- NPAP1 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as COSV61504347; called by muse, mutect2, varscan2
- NPAS3 | c.1858G>A p.A620T (on ENST00000356141 / NM_001164749.2; = p.A588T on NM_022123.3) | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs763025424, COSV60821859; called by muse, mutect2, varscan2
- NPTXR | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762426363, COSV60727668; called by muse, mutect2, varscan2
- NR1I3 | c.1031T>A p.M344K (on ENST00000367982 / NM_001077480.3; = p.M340K on NM_005122.5) | Missense Mutation (SNP) | VAF 187/224 reads (83%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as rs1558101795, COSV63467177; called by muse, mutect2, varscan2
- NR3C1 | c.1965G>T p.R655S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as COSV99196139; called by muse, mutect2, varscan2
- NUP160 | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as COSV65853448; called by muse, mutect2, varscan2
- NUP210L | c.4867A>G p.T1623A | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.985); catalogued as COSV55141348; called by muse, mutect2
- NUTM2D | c.44T>A p.L15* | Nonsense Mutation (SNP) | VAF 46/348 reads (13%) | catalogued as COSV101096873; called by muse, mutect2, varscan2
- OBI1 | c.2025G>A p.M675I | Missense Mutation (SNP) | VAF 67/100 reads (67%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV56144397; called by muse, mutect2, varscan2
- OBSCN | c.10429G>T p.A3477S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs780362343, COSV52738725, COSV52789463, COSV99482941; called by muse, mutect2, varscan2
- OPCML | c.613T>G p.L205V | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV59403557; called by muse, mutect2, varscan2
- OR10K1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 39/535 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs571768202, COSV56870491, COSV56872473; called by muse, mutect2
- OR10X1 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100936609; called by muse, mutect2
- OR10X1 | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100936611, COSV63768014; called by muse, mutect2
- OR13C2 | c.136A>T p.I46F | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV101604861; called by muse, mutect2, varscan2
- OR13C5 | c.280del p.L94Ffs*24 | Frame Shift Del (DEL) | VAF 38/70 reads (54%) | catalogued as COSV101053204, COSV66164601; called by mutect2, varscan2
- OR14A16 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV62926081; called by muse, mutect2, varscan2
- OR2A14 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 82/312 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as COSV68717877; called by muse, mutect2, varscan2
- OR2T10 | c.278C>G p.S93W | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57896065; called by muse, mutect2, varscan2
- OR4A5 | c.288G>T p.M96I | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.056); catalogued as rs148710182, COSV60521889; called by muse, mutect2, varscan2
- OR4D10 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV73259961; called by muse, mutect2, varscan2
- OR4N2 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 84/393 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs368630542, COSV60050638; called by muse, varscan2
- OR5D16 | c.246G>C p.M82I | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65721256; called by muse, mutect2, varscan2
- OR5W2 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV60614538; called by muse, mutect2, varscan2
- OR8D4 | c.928T>A p.S310T | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV58429405; called by muse, mutect2, varscan2
- OTUD6A | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.55); PolyPhen benign (0.066); catalogued as COSV57972586, COSV57973386; called by muse, mutect2, varscan2
- PALD1 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs761367866, COSV54970665; called by muse, mutect2, varscan2
- PAPPA2 | c.1872G>T p.R624S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62772676, COSV62774093; called by muse, mutect2, varscan2
- PAX1 | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV68271037; called by muse, mutect2, varscan2
- PCDH12 | c.3193C>T p.L1065F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV51519059; called by muse, mutect2, varscan2
- PCDHB4 | c.121G>C p.G41R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52019478, COSV52024742; called by muse, mutect2, varscan2
- PCDHB9 | c.1898G>T p.R633L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.822); catalogued as COSV53375191, COSV53379472; called by muse, mutect2, varscan2
- PCDHGB4 | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53896692; called by muse, mutect2, varscan2
- PCSK5 | c.284C>A p.S95* | Nonsense Mutation (SNP) | VAF 41/73 reads (56%) | catalogued as COSV65083391; called by muse, mutect2, varscan2
- PDCD2 | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs140493653, COSV99388406; called by muse, mutect2, varscan2
- PDE3A | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 16/103 reads (16%) | catalogued as rs767099881, COSV62967117, COSV62967623, COSV62977765; called by muse, varscan2
- PDHA2 | c.800C>A p.A267E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99756633; called by muse, mutect2, varscan2
- PDIA5 | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV60247053; called by muse, mutect2, varscan2
- PLCB1 | c.696T>C p.F232= | Splice Region (SNP) | VAF 49/115 reads (43%) | catalogued as COSV62037757; called by muse, mutect2, varscan2
- PLCG2 | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100842120, COSV63875469; called by muse, mutect2, varscan2
- PLEC | c.13378G>A p.D4460N (on ENST00000322810 / NM_201380.4; = p.D4350N on NM_000445.5) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs782787833, COSV59602824, COSV59633237; called by muse, mutect2, varscan2
- PLK4 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV54636237; called by muse, mutect2, varscan2
- PLXDC1 | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV59549401; called by muse, mutect2, varscan2
- PLXNA4 | c.4069C>A p.Q1357K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58104264; called by muse, varscan2
- PMFBP1 | c.2012G>T p.R671L (on ENST00000537465; = p.R666L on NM_031293.3) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV52820493, COSV52831489; called by muse, mutect2, varscan2
- POLE | c.5675G>A p.S1892N | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57673958; called by muse, mutect2, varscan2
- POLN | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV67023296; called by muse, mutect2, varscan2
- POLR3A | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV64930196; called by muse, mutect2, varscan2
- PPOX | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV57086629; called by muse, mutect2
- PRDM2 | c.2506G>T p.G836C | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs1295166423, COSV52442747; called by muse, mutect2, varscan2
- PSD2 | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51197075, COSV51197165; called by mutect2, varscan2
- PSME4 | c.4729+1G>T p.X1577_splice | Splice Site (SNP) | VAF 21/93 reads (23%) | catalogued as COSV101122356; called by muse, mutect2, varscan2
- PTN | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.973); catalogued as COSV100781001, COSV61963233; called by muse, mutect2, varscan2
- PTPRD | c.2633A>T p.D878V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV61927860; called by muse, mutect2, varscan2
- PTPRU | c.2391G>T p.Q797H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60521566; called by muse, mutect2, varscan2
- PTPRZ1 | c.5448G>T p.W1816C | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66430055; called by muse, mutect2, varscan2
- PXDN | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1173248098, COSV53226187; called by muse, mutect2, varscan2
- PYGM | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV99376870; called by muse, mutect2
- RABEP2 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 61/126 reads (48%) | catalogued as COSV100706794, COSV62868423; called by muse, mutect2, varscan2
- RAP1A | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62726125; called by muse, mutect2, varscan2
- RASSF2 | c.722C>G p.P241R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65081624, COSV99062214; called by muse, mutect2, varscan2
- RBAK | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62330769; called by muse, mutect2, varscan2
- RBP2 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.271); catalogued as COSV51672791; called by muse, mutect2, varscan2
- REG1A | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52068249; called by muse, mutect2, varscan2
- RGS7 | c.130C>A p.R44S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58530073, COSV58530443; called by muse, mutect2, varscan2
- RIMBP2 | c.2135C>A p.S712Y | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV55464055; called by muse, mutect2, varscan2
- RIMS2 | c.2835A>G p.I945M (on ENST00000666250 / NM_001348490.2; = p.I753M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.33); catalogued as COSV51652486; called by muse, mutect2, varscan2
- ROR2 | c.417C>A p.N139K | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100995413, COSV65216355; called by muse, mutect2, varscan2
- RTN1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.39); PolyPhen benign (0.188); catalogued as COSV50718699, COSV50719661; called by muse, mutect2, varscan2
- RTN1 | c.308C>G p.S103W | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs770484962, COSV50718708; called by muse, mutect2, varscan2
- RUNDC1 | c.878A>G p.Q293R | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as rs1166896440, COSV64512719; called by muse, mutect2, varscan2
- RUNX1T1 | c.548C>G p.P183R (on ENST00000265814 / NM_001198628.1; = p.P156R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56137178, COSV56139942, COSV56141276; called by muse, mutect2, varscan2
- RYR3 | c.3290G>T p.G1097V | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212405, COSV66777284; called by muse, mutect2, varscan2
- SATB2 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.898); catalogued as COSV53477876; called by muse, mutect2, varscan2
- SCML4 | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); catalogued as COSV64633823, COSV64635658; called by muse, mutect2, varscan2
- SCN2A | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51831522; called by muse, mutect2, varscan2
- SERPINA7 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV59664705; called by muse, mutect2, varscan2
- SF3B2 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59426910; called by muse, mutect2, varscan2
- SGIP1 | c.812C>A p.P271Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.282); catalogued as COSV52762678; called by muse, mutect2, varscan2
- SGIP1 | c.2170C>G p.Q724E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52762695; called by muse, mutect2, varscan2
- SGO2 | c.521T>A p.M174K | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV63413791; called by muse, mutect2, varscan2
- SHANK1 | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV53242686, COSV53255654; called by muse, mutect2, varscan2
- SHE | c.364A>G p.N122D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV59070762; called by muse, mutect2
- SIGLEC12 | c.220A>T p.I74F | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52459187, COSV52461858; called by muse, mutect2, varscan2
- SIRPB1 | c.146C>A p.S49* | Nonsense Mutation (SNP) | VAF 42/57 reads (74%) | catalogued as COSV53537330; called by muse, varscan2
- SLAMF8 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV56987489; called by muse, mutect2
- SLC12A9 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.042); catalogued as COSV51931057, COSV51931164; called by muse, mutect2, varscan2
- SLC13A5 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.7); PolyPhen benign (0.052); catalogued as rs777184227, COSV53421606; called by muse, mutect2, varscan2
- SLC25A14 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV54416842; called by muse, mutect2, varscan2
- SLC30A10 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV63070398; called by muse, varscan2
- SLC35F1 | c.976T>G p.C326G | Missense Mutation (SNP) | VAF 134/287 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV64498577; called by muse, mutect2, varscan2
- SLC4A8 | c.2998G>T p.E1000* | Nonsense Mutation (SNP) | VAF 74/202 reads (37%) | catalogued as COSV60647458; called by muse, mutect2, varscan2
- SLC52A3 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV54076555; called by muse, mutect2, varscan2
- SLC5A11 | c.1379C>A p.P460Q | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771062363, COSV61739935; called by muse, mutect2, varscan2
- SLC6A17 | c.1347G>T p.M449I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.95); catalogued as COSV58991242; called by muse, mutect2, varscan2
- SLITRK1 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV65674186; called by muse, mutect2, varscan2
- SMAD1 | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57470104; called by muse, mutect2, varscan2
- SNCA | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM1314259, COSV61131631; called by muse, mutect2, varscan2
- SNRPN | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57593983; called by muse, mutect2, varscan2
- SORCS1 | c.2802G>T p.L934F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV53840639; called by muse, mutect2, varscan2
- SORCS1 | c.1608C>A p.Y536* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV53840653; called by muse, mutect2, varscan2
- SPAM1 | c.53G>C p.S18T | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as rs774245869, COSV56141112; called by muse, mutect2, varscan2
- SPATA31D1 | c.2749G>A p.G917S | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs540950546, COSV100782848, COSV61192670; called by muse, mutect2, varscan2
- SPON1 | c.658C>A p.H220N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV59957339; called by muse, mutect2, varscan2
- SPTA1 | c.1546C>A p.Q516K | Missense Mutation (SNP) | VAF 147/179 reads (82%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs904442919, COSV100935071, COSV63748689; called by muse, mutect2, varscan2
- SPTAN1 | c.1656G>C p.L552F | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63985375; called by muse, mutect2, varscan2
- SPTBN4 | c.3539G>A p.G1180D | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58943339; called by muse, mutect2, varscan2
- ST18 | c.1595-1G>A p.X532_splice | Splice Site (SNP) | VAF 16/66 reads (24%) | catalogued as COSV52483937; called by muse, mutect2, varscan2
- ST8SIA6 | c.922_923insT p.A308Vfs*7 | Frame Shift Ins (INS) | VAF 82/361 reads (23%) | catalogued as COSV101112115; called by pindel, varscan2
- STAB2 | c.2542G>T p.G848W | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV66333954; called by muse, mutect2, varscan2
- STAT2 | c.1876T>A p.Y626N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV58474211; called by muse, mutect2, varscan2
- STXBP5L | c.1739T>C p.L580P | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV56499496; called by muse, mutect2, varscan2
- SV2B | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as rs753139153, COSV57698412; called by muse, mutect2, varscan2
- SVIL | c.2009+1G>A p.X670_splice | Splice Site (SNP) | VAF 54/198 reads (27%) | catalogued as rs754851303, COSV63439625; called by muse, mutect2, varscan2
- SYCP2L | c.1453C>A p.P485T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV51649826; called by muse, mutect2, varscan2
- TAAR6 | c.51C>A p.N17K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as COSV51582599; called by muse, mutect2, varscan2
- TAF2 | c.1092-1G>T p.X364_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | catalogued as COSV65416448; called by muse, mutect2
- TARS2 | c.1539+1G>T p.X513_splice | Splice Site (SNP) | VAF 49/393 reads (12%) | catalogued as COSV64694464; called by muse, mutect2, varscan2
- TAS1R3 | c.1930C>A p.L644I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100229336; called by muse, mutect2, varscan2
- TAS2R19 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.9); PolyPhen benign (0.06); catalogued as COSV101114398; called by muse, mutect2, varscan2
- TCF20 | c.4743G>T p.R1581S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs761776619, COSV59488167; called by muse, mutect2, varscan2
- TCHH | c.5473G>A p.E1825K | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); catalogued as COSV64272711; called by muse, mutect2
- TENT5A | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.399); catalogued as COSV100198813; called by muse, mutect2, varscan2
- TEX35 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.039); catalogued as rs923758738, COSV51103128; called by muse, mutect2, varscan2
- TIAM1 | c.4099G>A p.G1367R | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54537116; called by muse, mutect2, varscan2
- TMC3 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV63922136; called by muse, mutect2, varscan2
- TMEM182 | c.331A>T p.I111F | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV68424191; called by muse, mutect2, varscan2
- TMPRSS11F | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371744099, COSV62464540; called by muse, mutect2, varscan2
- TMTC1 | c.483G>T p.V161= (on ENST00000539277 / NM_001193451.2; = p.V53= on NM_175861.3) | Splice Region (SNP) | VAF 83/111 reads (75%) | catalogued as COSV55474909; called by muse, mutect2, varscan2
- TMTC3 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57122251; called by muse, mutect2, varscan2
- TNFSF14 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV104368860, COSV55589771; called by muse, mutect2, varscan2
- TP53 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as CM103214, COSV52683572; called by muse, mutect2, varscan2
- TPD52L3 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs757070996, COSV58828402; called by muse, mutect2, varscan2
- TRAF7 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV58212696; called by muse, mutect2, varscan2
- TRIM51 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV55263539; called by muse, mutect2, varscan2
- TRPM3 | c.2716C>G p.Q906E (on ENST00000357533 / NM_001366142.2; = p.Q749E on NM_020952.6) | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100677256, COSV62579625; called by muse, mutect2, varscan2
- TRRAP | c.1737G>T p.K579N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV62838574; called by muse, mutect2, varscan2
- TTLL11 | c.1143C>G p.I381M | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV58642005; called by muse, mutect2, varscan2
- TTN | c.54172C>G p.L18058V (on ENST00000591111; = p.L10634V on NM_003319.4) | Missense Mutation (SNP) | VAF 28/157 reads (18%) | PolyPhen probably damaging (0.996); catalogued as COSV59881007; called by muse, mutect2, varscan2
- UACA | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59853197; called by muse, mutect2, varscan2
- UBA1 | c.2468A>G p.D823G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV60111148; called by muse, mutect2, varscan2
- UBA7 | c.533C>G p.T178R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs370611357; called by muse, mutect2, varscan2
- UBC | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 170/422 reads (40%) | catalogued as rs754625391, COSV60058123; called by muse, varscan2
- UBE3A | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.119); catalogued as COSV51660938, COSV51663464, COSV51665821; called by muse, mutect2, varscan2
- URB2 | c.2500G>C p.V834L | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV50981127; called by muse, mutect2, varscan2
- UTRN | c.5531A>G p.N1844S | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs778471797, COSV62328451, COSV62348767; called by muse, mutect2, varscan2
- VIRMA | c.5372G>T p.G1791V | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.846); catalogued as COSV52581596; called by muse, mutect2, varscan2
- WDFY3 | c.986A>G p.K329R | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV55693165; called by muse, mutect2, varscan2
- WDR12 | c.41+2T>C p.X14_splice | Splice Site (SNP) | VAF 44/101 reads (44%) | catalogued as COSV99651006; called by muse, mutect2, varscan2
- WIPF1 | c.674A>T p.N225I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV55811269; called by muse, mutect2, varscan2
- YTHDC2 | c.3125G>T p.R1042I | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV50736520; called by muse, mutect2, varscan2
- ZFHX4 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.387); catalogued as COSV50489075; called by muse, mutect2, varscan2
- ZFHX4 | c.2315G>A p.C772Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50489243; called by muse, mutect2, varscan2
- ZNF142 | c.3238G>A p.G1080S (on ENST00000411696 / NM_001379660.1; = p.G880S on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs766031608, COSV68742940; called by muse, mutect2, varscan2
- ZNF33B | c.883G>T p.G295W | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV100847798, COSV63941819; called by muse, mutect2, varscan2
- ZNF454 | c.1427C>A p.A476D | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100194701; called by muse, mutect2, varscan2
- ZNF467 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV100117840; called by muse, mutect2, varscan2
- ZNF518B | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 97/268 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); catalogued as COSV58721253; called by muse, mutect2, varscan2
- ZNF692 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV60658718; called by muse, mutect2, varscan2
- ZNF713 | c.622G>T p.D208Y (on ENST00000633730 / NM_001366796.2; = p.D221Y on NM_182633.3) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.453); catalogued as COSV70056381; called by muse, mutect2, varscan2
- ZNF816 | c.405G>C p.L135F | Missense Mutation (SNP) | VAF 112/199 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV54410345, COSV54412072; called by muse, mutect2, varscan2
- ZNF836 | c.2027C>A p.T676N | Missense Mutation (SNP) | VAF 75/119 reads (63%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.559); catalogued as COSV100440703; called by muse, mutect2, varscan2
- ATP5F1A | c.778_780del p.V260del | In Frame Del (DEL) | VAF 24/80 reads (30%) | called by mutect2, pindel, varscan2
- DDB1 | c.1764del p.R589Afs*4 | Frame Shift Del (DEL) | VAF 30/54 reads (56%) | called by mutect2, pindel*, varscan2
- DMP1 | c.1110del p.T371Qfs*5 | Frame Shift Del (DEL) | VAF 48/119 reads (40%) | called by mutect2, varscan2
- EEF1G | c.972dup p.E325Rfs*6 | Frame Shift Ins (INS) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- FRG2 | c.402C>A p.N134K | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FRG2C | c.646G>T p.G216W | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGKV1-12 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- IGKV1D-16 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 130/279 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- LAMA4 | c.788del p.P263Lfs*9 (on ENST00000230538 / NM_001105206.3; = p.P263Lfs*11 on NM_002290.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- LRP1B | c.9887dup p.H3296Qfs*8 | Frame Shift Ins (INS) | VAF 15/131 reads (11%) | called by mutect2, varscan2
- LRP1B | c.9886C>A p.H3296N | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by mutect2, varscan2
- MRC1 | c.1534C>T p.H512Y | Missense Mutation (SNP) | VAF 115/238 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MUC16 | c.14995dup p.Q4999Pfs*38 | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- OR5T1 | c.914G>C p.R305P | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PAQR3 | c.571_580del p.H191Tfs*22 | Frame Shift Del (DEL) | VAF 28/172 reads (16%) | called by mutect2, pindel, varscan2
- POTEH | c.497_498delinsA p.M166Kfs*38 | Frame Shift Del (DEL) | VAF 51/296 reads (17%) | called by pindel, varscan2*
- PRAMEF10 | c.1145T>A p.F382Y | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SEC24A | c.666G>T p.R222S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.977); called by muse, mutect2
- SLC8B1 | c.1667_1668dup p.G557Mfs*10 | Frame Shift Ins (INS) | VAF 43/95 reads (45%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 117/286 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- TPTE | c.697del p.D233Mfs*5 (on ENST00000618007 / NM_199261.4; = p.D215Mfs*5 on NM_199259.4) | Frame Shift Del (DEL) | VAF 53/482 reads (11%) | called by mutect2, pindel, varscan2
- TRAV17 | c.230A>T p.H77L | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACSL1 | c.213A>G p.R71= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV55660557; called by muse, mutect2, varscan2
- ADAMTS12 | c.2016A>T p.I672= | Silent (SNP) | VAF 35/168 reads (21%) | catalogued as COSV61255274; called by muse, mutect2, varscan2
- ADGRV1 | c.2037G>T p.R679= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV67978215; called by muse, mutect2, varscan2
- ALK | c.1755C>A p.A585= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV66556938; called by muse, mutect2, varscan2
- ALPK3 | c.687G>T p.G229= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV51929087, COSV51936517; called by muse, mutect2, varscan2
- ANK1 | c.3027G>C p.L1009= | Silent (SNP) | VAF 87/149 reads (58%) | catalogued as COSV55872538; called by muse, mutect2, varscan2
- ANKRD26 | c.117C>A p.G39= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as COSV65792791, COSV65795069; called by muse, mutect2, varscan2
- ARSK | c.30A>T p.A10= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV62453342; called by muse, mutect2, varscan2
- ASPM | c.2247G>A p.E749= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV54124420, COSV99660880; called by muse, mutect2, varscan2
- B3GLCT | c.936G>A p.V312= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV100587330, COSV58453238; called by muse, mutect2, varscan2
- BEST3 | c.1632C>T p.G544= | Silent (SNP) | VAF 73/154 reads (47%) | catalogued as COSV58298693; called by muse, mutect2, varscan2
- BORCS6 | c.567G>T p.A189= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV66505140; called by muse, mutect2, varscan2
- BPIFB4 | c.718C>A p.R240= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs752406178, COSV64950589, COSV64950633; called by muse, mutect2, varscan2
- CA4 | c.855G>T p.G285= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV56280766; called by muse, varscan2
- CAPN3 | c.360C>T p.D120= | Silent (SNP) | VAF 64/109 reads (59%) | catalogued as rs886043027, COSV58819187; called by muse, mutect2, varscan2
- CD1C | c.642C>A p.P214= | Silent (SNP) | VAF 29/221 reads (13%) | catalogued as COSV63805658, COSV63807173; called by muse, mutect2, varscan2
- CES5A | c.1650C>T p.S550= (on ENST00000290567 / NM_001143685.2; = p.S500= on NM_145024.3) | Silent (SNP) | VAF 104/191 reads (54%) | catalogued as COSV51863479; called by muse, mutect2, varscan2
- COL7A1 | c.1326T>A p.R442= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as COSV60390994; called by muse, mutect2, varscan2
- CPB2 | c.33C>A p.P11= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as rs947699992, COSV51672233; called by muse, mutect2, varscan2
- CYP8B1 | c.123C>G p.P41= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100296317, COSV60225580; called by muse, mutect2, varscan2
- DENND5B | c.3690C>A p.A1230= | Silent (SNP) | VAF 109/131 reads (83%) | catalogued as COSV60899714; called by muse, mutect2, varscan2
- DHX15 | c.42C>G p.P14= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV61025609; called by muse, mutect2
- DNAH9 | c.10416C>A p.G3472= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as COSV52333497; called by muse, mutect2, varscan2
- DYNC1H1 | c.8142C>T p.P2714= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV64134266; called by muse, mutect2, varscan2
- EDARADD | c.387G>T p.L129= (on ENST00000334232 / NM_145861.4; = p.L119= on NM_080738.4) | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV62061055; called by muse, mutect2, varscan2
- FAT2 | c.3327A>C p.A1109= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV55813018; called by muse, mutect2, varscan2
- FCRL3 | c.1407C>A p.V469= | Silent (SNP) | VAF 36/791 reads (5%) | catalogued as COSV63839341; called by muse, mutect2
- FMR1NB | c.216C>T p.L72= | Silent (SNP) | VAF 59/105 reads (56%) | catalogued as rs141506256, COSV65070997; called by muse, mutect2, varscan2
- GABRA6 | c.1065T>A p.P355= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as COSV50877487; called by muse, mutect2, varscan2
- GRM7 | c.1740C>T p.P580= | Silent (SNP) | VAF 46/89 reads (52%) | catalogued as COSV63128915; called by muse, mutect2, varscan2
- HECTD1 | c.3489G>T p.L1163= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as COSV67945019; called by muse, mutect2, varscan2
- HOXA3 | c.579C>A p.R193= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV57825057; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.204A>T p.G68= | Silent (SNP) | VAF 47/143 reads (33%) | called by muse, mutect2, varscan2
- IL4R | c.1884A>G p.E628= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV50138202; called by muse, mutect2, varscan2
- IMPG2 | c.2949G>T p.L983= | Silent (SNP) | VAF 51/101 reads (50%) | catalogued as COSV51973041; called by muse, mutect2, varscan2
- INHBA | c.1257C>A p.I419= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV54219452, COSV54219664; called by muse, mutect2, varscan2
- INTS14 | c.687C>T p.P229= (on ENST00000313182 / NM_001366360.2; = p.P150= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as rs1351002146, COSV57525588; called by muse, mutect2, varscan2
- JMJD1C | c.6261C>G p.A2087= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV59512583; called by muse, mutect2, varscan2
- JTB | c.102G>T p.V34= | Silent (SNP) | VAF 49/443 reads (11%) | catalogued as COSV55131352; called by muse, mutect2, varscan2
- KATNIP | c.1533G>A p.S511= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs533574674, COSV55173241; called by muse, mutect2, varscan2
- KHDRBS1 | c.912T>A p.R304= | Silent (SNP) | VAF 90/180 reads (50%) | catalogued as COSV56980640; called by muse, mutect2, varscan2
- KIF1B | c.552G>A p.L184= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV55803221; called by muse, mutect2, varscan2
- KIR3DL1 | c.639G>A p.L213= | Silent (SNP) | VAF 144/226 reads (64%) | catalogued as rs1227302405, COSV58487808; called by muse, mutect2, varscan2
- LCA5L | c.1956G>A p.V652= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as COSV55743792; called by muse, mutect2, varscan2
- LIM2 | c.291G>T p.R97= (on ENST00000596399 / NM_001161748.2; = p.R139= on NM_030657.4) | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV55740228; called by muse, mutect2, varscan2
- LMAN2L | c.24T>A p.L8= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV53840520; called by muse, mutect2, varscan2
- LRRC31 | c.1599A>G p.L533= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs776348651, COSV52979415; called by muse, mutect2, varscan2
- MUC16 | c.37950C>A p.T12650= | Silent (SNP) | VAF 48/169 reads (28%) | catalogued as COSV67443848; called by muse, mutect2, varscan2
- MYH13 | c.5649G>A p.K1883= | Silent (SNP) | VAF 92/159 reads (58%) | catalogued as COSV52820482; called by muse, mutect2, varscan2
- MYO1A | c.1683G>T p.P561= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV55651673; called by muse, varscan2
- NEB | c.1209G>A p.E403= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV50808491; called by muse, mutect2, varscan2
- NPIPA1 | c.969A>G p.S323= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as rs1161666379, COSV60153825; called by muse, mutect2, varscan2
- OR4C15 | c.1005C>G p.L335= (on ENST00000314644; = p.L281= on NM_001001920.2) | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV58950967, COSV58951059; called by muse, mutect2, varscan2
- OR5T3 | c.765T>A p.S255= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV57379382; called by muse, mutect2, varscan2
- PATJ | c.1254A>T p.I418= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV57155215; called by muse, mutect2, varscan2
- PAX4 | c.249T>A p.P83= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV58387266; called by muse, mutect2, varscan2
- PDHA2 | c.801A>G p.A267= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99756640; called by muse, mutect2, varscan2
- PDZD8 | c.1974C>T p.A658= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV57823253; called by muse, mutect2, varscan2
- PKD1 | c.7872G>T p.R2624= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV51910503; called by muse, mutect2, varscan2
- PLXNC1 | c.186C>T p.G62= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV51569211; called by muse, mutect2, varscan2
- POU6F1 | c.1119C>T p.P373= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV61325746; called by muse, mutect2, varscan2
- PRSS21 | c.762A>G p.G254= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV50051027; called by muse, mutect2, varscan2
- PTPRN2 | c.954G>T p.P318= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as rs776694017, COSV67021609; called by muse, mutect2, varscan2
- RAB34 | c.459G>A p.E153= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs778860083, COSV99972575; called by muse, mutect2, varscan2
- RANBP2 | c.615G>T p.S205= | Silent (SNP) | VAF 273/519 reads (53%) | catalogued as rs1223310052, COSV51695992; called by muse, mutect2, varscan2
- RANBP3 | c.876G>T p.T292= (on ENST00000340578 / NM_007322.3; = p.T287= on NM_003624.3) | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as COSV50380181; called by muse, mutect2, varscan2
- RC3H2 | c.2199G>T p.R733= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as COSV61798442; called by muse, mutect2, varscan2
- RGS3 | c.1728G>C p.L576= (on ENST00000350696 / NM_001282923.2; = p.L464= on NM_017790.4) | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV58276748; called by muse, mutect2, varscan2
- RIMS2 | c.4260G>A p.L1420= (on ENST00000666250 / NM_001348490.2; = p.L991= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 83/138 reads (60%) | catalogued as rs760190206, COSV51652525; called by muse, mutect2, varscan2
- RRP1B | c.1629T>G p.P543= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs759780239, COSV61478360; called by muse, mutect2, varscan2
- RYK | c.934A>C p.R312= (on ENST00000620660 / NM_001005861.2; = p.R309= on NM_002958.4) | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV99938318; called by muse, mutect2, varscan2
- RYR2 | c.12912C>A p.G4304= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as COSV63660677; called by muse, mutect2, varscan2
- SEC16A | c.1449G>T p.P483= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV51521379; called by muse, mutect2, varscan2
- SH3GL3 | c.891G>A p.E297= | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as COSV61053032; called by muse, mutect2, varscan2
- SHANK3 | c.972C>T p.I324= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV53183353, COSV53185196; called by muse, mutect2, varscan2
- SKAP1 | c.502C>T p.L168= | Silent (SNP) | VAF 92/211 reads (44%) | catalogued as COSV61143974; called by muse, mutect2, varscan2
- SLC27A4 | c.1284G>T p.L428= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV55958657; called by muse, mutect2, varscan2
- SLC4A9 | c.343C>A p.R115= (on ENST00000507527 / NM_001258428.2; = p.R91= on NM_031467.3) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV50197615, COSV99138538; called by muse, mutect2, varscan2
- SLC6A19 | c.1125C>T p.Y375= | Silent (SNP) | VAF 142/247 reads (57%) | catalogued as rs145782869, COSV58670613; called by muse, mutect2, varscan2
- SMYD1 | c.1086C>T p.S362= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs778573981, COSV70224397, COSV70226211; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.171C>A p.P57= | Silent (SNP) | VAF 53/87 reads (61%) | catalogued as COSV60320334; called by muse, mutect2, varscan2
- ST8SIA6 | c.603A>T p.G201= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as COSV66465630; called by muse, mutect2, varscan2
- STK10 | c.2103G>A p.K701= | Silent (SNP) | VAF 68/141 reads (48%) | catalogued as COSV51570397; called by muse, mutect2, varscan2
- TACC3 | c.438A>T p.P146= | Silent (SNP) | VAF 70/179 reads (39%) | catalogued as COSV100508705, COSV57602707; called by muse, mutect2, varscan2
- TDG | c.1143G>T p.G381= | Silent (SNP) | VAF 36/155 reads (23%) | catalogued as COSV57164977; called by muse, mutect2, varscan2
- TDP1 | c.843C>T p.T281= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV59642096; called by muse, mutect2, varscan2
- TENT4B | c.1860G>A p.G620= (on ENST00000561678 / NM_001365323.2; = p.G605= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as rs746553252, COSV100665787; called by muse, mutect2, varscan2
- TEX14 | c.1155C>A p.I385= (on ENST00000240361 / NM_001201457.2; = p.I379= on NM_031272.5) | Silent (SNP) | VAF 52/153 reads (34%) | catalogued as COSV53611543; called by muse, mutect2, varscan2
- TFB1M | c.351A>G p.V117= | Silent (SNP) | VAF 73/111 reads (66%) | catalogued as COSV65698199; called by muse, mutect2, varscan2
- TLR8 | c.1485C>T p.F495= (on ENST00000218032 / NM_138636.5; = p.F513= on NM_016610.4) | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as COSV54316314; called by muse, mutect2, varscan2
- TRAP1 | c.957G>T p.A319= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as rs747215207, COSV55914630; called by muse, mutect2, varscan2
- TTYH2 | c.990G>T p.L330= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV53908480, COSV53908587; called by muse, mutect2, varscan2
- ULK2 | c.1851C>G p.S617= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV64444140; called by muse, mutect2, varscan2
- USP31 | c.2994A>T p.V998= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV54849181; called by muse, mutect2, varscan2
- WDFY2 | c.450A>T p.G150= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV53286992; called by muse, varscan2
- ZFP90 | c.834G>T p.G278= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV101238720; called by muse, mutect2, varscan2
- ZMIZ2 | c.2721G>A p.T907= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs755305903, COSV54805908; called by muse, mutect2, varscan2
- ZNF454 | c.1428C>A p.A476= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV100194703; called by muse, mutect2, varscan2
- ZNF536 | c.2941C>A p.R981= | Silent (SNP) | VAF 38/68 reads (56%) | catalogued as COSV62817560, COSV62818086; called by muse, mutect2, varscan2
- AC073310.1 | n.1031C>G | RNA (SNP) | VAF 33/158 reads (21%) | called by muse, mutect2, varscan2
- DEFB119 | c.61+1206G>T | Intron (SNP) | VAF 65/173 reads (38%) | catalogued as COSV100190618, COSV100191274; called by muse, mutect2, varscan2
- HELLPAR | n.204923C>A | RNA (SNP) | VAF 130/281 reads (46%) | catalogued as COSV61702690; called by muse, mutect2, varscan2
- HOXA7 | c.*2G>T | 3'UTR (SNP) | VAF 23/36 reads (64%) | catalogued as COSV99636302; called by muse, varscan2
- IGKV1-13 | n.299C>T | RNA (SNP) | VAF 49/450 reads (11%) | catalogued as rs1439912996; called by muse, varscan2
- KIR3DX1 | n.372C>A | RNA (SNP) | VAF 33/50 reads (66%) | catalogued as COSV99683062; called by muse, mutect2, varscan2
- MIR1269A | n.60G>T | RNA (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- MRTFB | c.155-23208G>T | Intron (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100370950; called by muse, mutect2, varscan2
- PKM | c.1141-460G>T | Intron (SNP) | VAF 28/47 reads (60%) | catalogued as COSV58786800; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1183A>G | RNA (SNP) | VAF 117/255 reads (46%) | called by muse, mutect2, varscan2
- TUBB7P | n.975G>T | RNA (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2
- ZFHX3 | c.-533+100G>T | Intron (SNP) | VAF 22/55 reads (40%) | catalogued as COSV73947867; called by muse, mutect2, varscan2
